TCGA case TCGA-CV-A45P — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c509ba7-2edf-4428-bd39-109c78b3fb30

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 82.9 years (30,297 days); Year of diagnosis: 1998; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 639 days (1.7 years).
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 22; Margin status: Uninvolved.
   Treatment given: Treatment type: Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Mouth, NOS. Age at diagnosis: 84.7 years (30,936 days); Days to diagnosis: 639 days (1.7 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Floor of mouth, NOS. Age at diagnosis: 84.7 years (30,936 days); Days to diagnosis: 639 days (1.7 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 639 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mouth, NOS; Days to recurrence: 639 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Day 639 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Floor of mouth, NOS; Days to recurrence: 639 days (1.7 years); Evidence of recurrence type: Convincing Image Source.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-A45P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-CV-A45P-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CV-A45P-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-A45P-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 1; Alcohol history documented: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 639 days; disease-specific survival: no event (censored), 639 days; disease-free interval: event (new tumor event after initially disease-free), 639 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 639 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CV-A45P-01A-11D-A24C-01): tumor purity 0.38, ploidy 2.04, whole-genome doublings 0.
